Gene-level copy-number profile of tumor specimen TCGA-L5-A8NI-01A from TCGA case TCGA-L5-A8NI, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 79.8 years (29,135 days).
Specimen TCGA-L5-A8NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ca14dbcf-65e6-45ea-9a5f-def0c71b8731.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NI-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2f42a1c-66ab-4b19-a66a-cebb64eaf885

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 17,928; copy number 2: 37,157; copy number 3: 4,222; copy number 4: 331; copy number 5: 56; copy number 6: 76; copy number 7: 25; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NI-01A-11D-A37B-01): tumor purity 0.65, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:30,626,423–30,626,797, 1 gene: AC096921.1.
- chr5:64,768,930–65,018,750, 1 gene (within-gene range 0–1): CWC27.
- chr6:1,623,806–2,245,605, 1 gene (within-gene range 0–2): GMDS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 159 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,111,815–15,400,283, 8 genes, copy number 5 (within-gene range 3–5): TMEM51-AS1, TMEM51, C1orf195, MFFP1, ZBTB2P1, FHAD1, FHAD1-AS1, AL031283.2.
- chr1:203,212,827–203,353,651, 8 genes, copy number 5 (within-gene range 2–5): CHIT1, NPM1P40, LINC01353, LINC01136, BTG2, RNU6-487P, FMOD, AL359837.1.
- chr1:206,957,965–207,099,993, 5 genes, copy number 6: FCAMR, C1orf116, PFKFB2, YOD1, C4BPB.
- chr2:233,032,672–233,472,104, 10 genes, copy number 5 (within-gene range 4–5): NEU2, INPP5D, RN7SL32P, ATG16L1, SCARNA5, SCARNA6, SAG, AC013726.1, DGKD, Y_RNA.
- chr3:184,546,714–184,780,720, 8 genes, copy number 5: LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4.
- chr6:41,636,882–41,667,649, 2 genes, copy number 5: MDFI, NPM1P51.
- chr6:85,387,219–85,499,058, 5 genes, copy number 6: LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2.
- chr11:69,147,228–70,021,059, 21 genes, copy number 7–12: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1.
- chr11:73,760,563–73,931,114, 6 genes, copy number 7 (within-gene range 3–7): AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1.
- chr12:69,212,108–69,460,724, 11 genes, copy number 5: AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373.
- chr12:76,115,711–76,615,567, 10 genes, copy number 6: AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9.
- chr15:84,717,474–85,139,145, 11 genes, copy number 6 (within-gene range 3–6): AC012291.3, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A.
- chr19:44,228,729–45,038,198, 44 genes, copy number 6 (within-gene range 2–6): ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB.
- chr19:45,047,458–45,047,561, 1 gene, copy number 6: RNU6-611P.
- chr21:42,362,282–42,581,440, 9 genes, copy number 5 (within-gene range 2–5): TFF1, TMPRSS3, UBASH3A, RNU6-1149P, RSPH1, SLC37A1, AP001625.3, AP001625.1, AP001625.2.

Autosomal genes at a single copy (total copy number 1): 16,407. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
